Gene-level copy-number profile of tumor specimen TCGA-43-8115-01A from TCGA case TCGA-43-8115, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 72.3 years (26,406 days).
Specimen TCGA-43-8115-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.f46c26d2-42e0-4923-ab11-a1d6b52d305c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-43-8115-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0e54e946-25e5-46a5-b71f-c58f850cc6c5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 10,300; copy number 2: 37,579; copy number 3: 7,578; copy number 4: 2,883; copy number 5: 722; copy number 7: 1; copy number 10: 109; copy number 11: 1; copy number 12: 137; copy number 13: 509.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-43-8115-01A-11D-2243-01): tumor purity 0.42, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:104,063,039–104,063,582, 1 gene: RAP1BP2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,479 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:55,634,061–77,593,319, 430 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:99,400,475–99,490,035, 1 gene, copy number 11 (within-gene range 4–11): REV1.
- chr2:99,545,419–100,192,428, 1 gene, copy number 7 (within-gene range 2–11): AFF3.
- chr3:148,093,175–198,222,513, 902 genes, copy number 5–13 (within-gene range 3–13) (broad region; genes not listed).
- chr19:56,595,300–58,605,223, 145 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,300. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
